Somatic mutation profile of tumor specimen ALCH-B1OB-TTP1-A (aliquot ALCH-B1OB-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1OB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.0 years (25,941 days).
Specimen ALCH-B1OB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3762d7c9-91eb-4fd0-9419-6bd85bb4a4fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OB-NB1-A (Blood Derived Normal), aliquot ALCH-B1OB-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfd77f4f-babc-4c3b-9ad2-4a1a25ef6cf1

The open-access MAF lists 248 somatic variants for this specimen: 163 protein-altering or splice-affecting, 50 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 50, Nonsense Mutation 10, Intron 10, 3'UTR 10, Splice Site 7, 5'UTR 7, Frame Shift Del 7, RNA 5, 5'Flank 2, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 131/226 reads (58%) | catalogued as rs121913324, CD132642, CM044071, COSV58819862; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 45/96 reads (47%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by mutect2, varscan2
- AC069544.2 | c.706G>C p.G236R | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV65684458; called by muse, mutect2
- ACSF2 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 37/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765996539; called by muse, mutect2
- ANKRD17 | c.5422C>T p.R1808C | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); catalogued as COSV58217044; called by muse, mutect2, varscan2
- AOX1 | c.3463G>A p.E1155K | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs200842175, COSV99613823; called by muse, mutect2
- APC | c.2006T>G p.L669* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as CM1110395, COSV57353329; called by muse, mutect2, varscan2
- BCAN | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 45/926 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749535108, COSV100228391; called by muse, mutect2
- CARD9 | c.1435-1G>A p.X479_splice | Splice Site (SNP) | VAF 26/86 reads (30%) | catalogued as rs1353243639; called by muse, mutect2
- CCDC178 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100285080; called by muse, varscan2
- CD55 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1367527886; called by muse, mutect2, varscan2
- CRACR2B | c.683C>A p.P228Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1374124773; called by muse, mutect2, varscan2
- CYP27B1 | c.1067G>C p.S356T | Missense Mutation (SNP) | VAF 48/508 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as CM138515; called by muse, mutect2
- DNAH8 | c.8947A>G p.R2983G | Missense Mutation (SNP) | VAF 58/406 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs1217315111; called by muse, mutect2, varscan2
- ERICH3 | c.2278C>A p.Q760K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100445191; called by muse, mutect2, varscan2
- FBN1 | c.1880G>T p.R627L | Missense Mutation (SNP) | VAF 34/517 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as COSV57311022, COSV57328035; called by muse, mutect2
- GABRA5 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59479904; called by mutect2, varscan2
- GRID2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779054312, COSV56289101; called by muse, mutect2, varscan2
- IRS4 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs771876367; called by muse, mutect2, varscan2
- ITGAM | c.3032T>G p.F1011C (on ENST00000648685 / NM_001145808.2; = p.F1010C on NM_000632.4) | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1355757971; called by muse, mutect2
- ITIH4 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477366648; called by muse, mutect2
- ITPRID1 | c.1533G>T p.M511I | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60078670; called by muse, mutect2, varscan2
- JUN | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 121/432 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64664673; called by muse, mutect2, varscan2
- KCNH4 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.467); catalogued as rs1337185389; called by muse, mutect2, varscan2
- KEAP1 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 102/158 reads (65%) | SIFT tolerated (0.51); PolyPhen benign (0.048); catalogued as COSV99408145; called by muse, mutect2, varscan2
- MAP2K4 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV62256162; called by muse, mutect2
- MXRA5 | c.6184G>A p.G2062R | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247186709; called by muse, mutect2, varscan2
- MYLK3 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV67363341; called by muse, mutect2, varscan2
- NLRP3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 132/691 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs769647268, CM1414461, COSV60220167; called by muse, mutect2, varscan2
- NUCB2 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100083058; called by muse, mutect2, varscan2
- OGFR | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.047); catalogued as rs919445986, COSV51701060; called by muse, mutect2
- OR5D16 | c.489C>A p.C163* | Nonsense Mutation (SNP) | VAF 40/159 reads (25%) | catalogued as COSV65722193; called by muse, mutect2, varscan2
- OSBPL8 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99674632; called by muse, mutect2
- PDE8A | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs940749948; called by muse, mutect2, varscan2
- PTPN3 | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as rs1469346763; called by muse, mutect2, varscan2
- RAB24 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 83/544 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1054074759, COSV100293592; called by muse, mutect2, varscan2
- REST | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV58359965; called by muse, mutect2, varscan2
- RIBC2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs764961769; called by muse, mutect2, varscan2
- RYR1 | c.11715G>C p.Q3905H | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100614192, COSV62098985; called by muse, mutect2, varscan2
- RYR2 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 112/331 reads (34%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.736); catalogued as rs373326624, COSV63684169, COSV63713339; called by muse, mutect2, varscan2
- SLITRK4 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs906371486; called by muse, mutect2
- SNAP47 | c.503C>G p.T168R | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV59918507; called by muse, mutect2
- TALDO1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs1391258906, COSV100032914, COSV59798145; called by muse, mutect2, varscan2
- TAS2R7 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs369634234; called by muse, mutect2, varscan2
- TCF23 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 26/222 reads (12%) | catalogued as COSV99940404; called by muse, varscan2
- TCF23 | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1255926756; called by muse, mutect2, varscan2
- THSD7B | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 88/364 reads (24%) | catalogued as COSV99754199; called by muse, mutect2, varscan2
- TMC3 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100845838; called by muse, mutect2
- TMED5 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs202135933; called by muse, mutect2, varscan2
- TMEM132A | c.1438C>T p.R480C (on ENST00000453848 / NM_178031.3; = p.R481C on NM_017870.4) | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs151003082; called by muse, mutect2, varscan2
- TMPRSS11B | c.1126A>G p.R376G | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs771143025; called by muse, mutect2, varscan2
- TRRAP | c.10711G>A p.V3571M (on ENST00000359863 / NM_001244580.1; = p.V3542M on NM_003496.3) | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62854069; called by muse, mutect2, varscan2
- TSHZ1 | c.2226C>A p.F742L (on ENST00000580243 / NM_001308210.2; = p.F697L on NM_005786.6) | Missense Mutation (SNP) | VAF 46/506 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV59018245; called by muse, mutect2
- TSR3 | c.932G>C p.R311T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV50104014; called by muse, mutect2, varscan2
- TTC7B | c.354C>A p.N118K | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs773724780; called by muse, mutect2
- TYK2 | c.3308G>A p.S1103N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs757843261; called by muse, varscan2
- WSCD2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as COSV54587498; called by muse, mutect2, varscan2
- ZNF239 | c.626G>C p.C209S | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60018011; called by muse, mutect2, varscan2
- ZNF688 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1041737232; called by muse, mutect2, varscan2
- ABCA2 | c.1226C>G p.P409R (on ENST00000614293; = p.P379R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AC069544.2 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2
- ACACB | c.972del p.N325Ifs*10 | Frame Shift Del (DEL) | VAF 82/242 reads (34%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AIPL1 | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 147/270 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD26 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- APC | c.1560_1566del p.C520* | Frame Shift Del (DEL) | VAF 16/176 reads (9%) | called by mutect2, pindel
- ASPHD2 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- AUTS2 | c.3229G>A p.D1077N | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); called by muse, mutect2
- BMPR2 | c.589T>C p.S197P | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- C1orf216 | c.600G>C p.E200D | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- CD248 | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- CFAP54 | c.3666C>G p.D1222E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.27); called by muse, varscan2
- CHD3 | c.5639C>A p.T1880N (on ENST00000330494 / NM_001005273.3; = p.T1846N on NM_005852.4) | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CLRN3 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- COL1A2 | c.3086A>C p.Q1029P | Missense Mutation (SNP) | VAF 136/412 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- DDX3Y | c.950T>G p.L317W | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGCR2 | c.1202_1216del p.Y401_G405del | In Frame Del (DEL) | VAF 85/293 reads (29%) | called by mutect2, pindel, varscan2
- DHCR24 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 49/443 reads (11%) | called by muse, mutect2, varscan2
- DLL3 | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- DNAH5 | c.9336C>G p.D3112E | Missense Mutation (SNP) | VAF 18/654 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DOCK10 | c.5555T>C p.L1852P | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DST | c.6371C>T p.S2124L | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- DTL | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 233/360 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DZIP1 | c.2527C>G p.L843V (on ENST00000347108; = p.L824V on NM_014934.5) | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EFTUD2 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EIF2B5 | c.1238G>T p.G413V (on ENST00000647909; = p.G405V on NM_003907.3) | Missense Mutation (SNP) | VAF 19/638 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2
- EPB41L2 | c.2399T>C p.V800A | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPS8L1 | c.1825_1837del p.L609Afs*47 (on ENST00000201647 / NM_133180.3; = p.L482Afs*47 on NM_017729.3) | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | called by pindel, varscan2
- ERICH5 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FAM110B | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM205A | c.1224T>A p.S408R | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- FAM24B | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBLIM1 | c.825C>G p.C275W | Missense Mutation (SNP) | VAF 40/367 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); called by muse, mutect2
- FUT6 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GDF10 | c.1301T>A p.I434N | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GGN | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- GPHN | c.2169C>G p.H723Q (on ENST00000315266 / NM_001377519.1; = p.H756Q on NM_020806.5) | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2
- GPR182 | c.110dup p.N37Kfs*6 | Frame Shift Ins (INS) | VAF 99/372 reads (27%) | called by mutect2, pindel, varscan2
- GPX3 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- HEATR3 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- HGF | c.1705del p.Q569Sfs*13 | Frame Shift Del (DEL) | VAF 44/133 reads (33%) | called by mutect2, pindel, varscan2
- INTS4 | c.2714-1G>C p.X905_splice | Splice Site (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- ISLR2 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- ITCH | c.2463T>G p.N821K (on ENST00000262650 / NM_001257137.3; = p.N780K on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ITPRID2 | c.258-2A>G p.X86_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2309_2335del p.D770_E778del (on ENST00000359125 / NM_172107.4; = p.D742_E750del on NM_004518.6) | In Frame Del (DEL) | VAF 18/133 reads (14%) | called by mutect2, pindel
- KIAA0100 | c.1808T>C p.L603P | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KIF1B | c.2845A>G p.T949A (on ENST00000377086 / NM_001365952.1; = p.T903A on NM_015074.3) | Missense Mutation (SNP) | VAF 113/311 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF5A | c.2385C>G p.H795Q | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- MAPK11 | c.596A>C p.H199P | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2
- MAPK8IP1 | c.528_529del p.L177Efs*2 | Frame Shift Del (DEL) | VAF 72/442 reads (16%) | called by pindel, varscan2
- MBD1 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 68/407 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- MOCOS | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO6 | c.1224-2A>G p.X408_splice | Splice Site (SNP) | VAF 35/50 reads (70%) | called by muse, mutect2, varscan2
- NEK8 | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 141/376 reads (38%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- NFX1 | c.1572G>C p.Q524H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- NHS | c.3500C>T p.S1167L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- NID2 | c.3498C>G p.I1166M | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NPAS3 | c.1053T>A p.S351R (on ENST00000356141 / NM_001164749.2; = p.S319R on NM_022123.3) | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- NXPE3 | c.907C>G p.P303A | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.159); called by muse, mutect2
- OSGEP | c.35A>T p.N12I | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OTOF | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALB2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.542C>G p.S181W | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2
- PAQR9 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 117/313 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDH11X | c.2285T>A p.L762H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGC3 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 22/305 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); called by muse, mutect2
- PLD6 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PPP4R3A | c.1355T>A p.L452H (on ENST00000554943 / NM_001366432.1; = p.L439H on NM_001284280.1) | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PROSER2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- RANGRF | c.242A>T p.H81L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RBM43 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- RECQL5 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RFPL2 | c.904A>C p.K302Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.115); called by muse, mutect2
- ROBO1 | c.3757G>T p.V1253L | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- RPRD2 | c.3111dup p.G1038Wfs*16 | Frame Shift Ins (INS) | VAF 77/439 reads (18%) | called by mutect2, pindel, varscan2
- RRN3 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- RTBDN | c.554C>G p.S185C (on ENST00000393233 / NM_001270444.1; = p.S217C on NM_031429.2) | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RUBCN | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- RYR2 | c.14591-1G>T p.X4864_splice | Splice Site (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- SERPINI2 | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- SETBP1 | c.2034G>C p.L678F | Missense Mutation (SNP) | VAF 84/658 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SI | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC4A11 | c.137-4C>G | Splice Region (SNP) | VAF 21/330 reads (6%) | called by muse, mutect2
- SLFN14 | c.2164C>G p.Q722E | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SPAG9 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- SPHK2 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- SPRR4 | c.234_*23del | Nonstop Mutation (DEL) | VAF 31/254 reads (12%) | called by mutect2, pindel
- SPTA1 | c.4873G>T p.E1625* | Nonsense Mutation (SNP) | VAF 140/743 reads (19%) | called by muse, mutect2, varscan2
- SPTBN5 | c.1609A>T p.S537C | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SRRM1 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 98/329 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STOX1 | c.411G>C p.Q137H | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- STRIP2 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TANK | c.404+2T>C p.X135_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | called by muse, varscan2
- TIMM10 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TMEM241 | c.280-2A>T p.X94_splice | Splice Site (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- TNFRSF9 | c.535A>T p.R179* | Nonsense Mutation (SNP) | VAF 54/166 reads (33%) | called by muse, mutect2, varscan2
- TRIM39 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIM67 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.055); called by muse, mutect2
- TYK2 | c.3315del p.T1106Rfs*7 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by pindel, varscan2
- UNC80 | c.4867G>C p.E1623Q | Missense Mutation (SNP) | VAF 120/245 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- VIPR2 | c.1079_1085del p.E360Afs*17 | Frame Shift Del (DEL) | VAF 26/250 reads (10%) | called by mutect2, pindel
- ZNF764 | c.1206G>C p.E402D | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.107); called by muse, mutect2
- ABCA5 | c.1893G>A p.G631= | Silent (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- ADCY10 | c.3861G>C p.L1287= | Silent (SNP) | VAF 56/960 reads (6%) | called by muse, mutect2
- ARID3A | c.1737G>A p.G579= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs1370205272; called by muse, varscan2
- ASXL2 | c.24G>A p.K8= | Silent (SNP) | VAF 53/210 reads (25%) | catalogued as rs1343028890; called by muse, mutect2, varscan2
- CACHD1 | c.2637C>T p.L879= | Silent (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- CEBPZ | c.3042A>G p.R1014= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs756236129; called by muse, mutect2, varscan2
- CFAP20DC | c.909G>A p.E303= (on ENST00000482387 / NM_001351530.2; = p.E178= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- CHD6 | c.7839C>T p.L2613= | Silent (SNP) | VAF 53/156 reads (34%) | catalogued as rs948256098; called by muse, mutect2, varscan2
- CHD9 | c.2550A>G p.Q850= | Silent (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- CHRNA6 | c.1044G>A p.L348= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- CPA4 | c.690T>C p.Y230= | Silent (SNP) | VAF 27/263 reads (10%) | called by muse, mutect2, varscan2
- CTNND2 | c.3243C>T p.I1081= | Silent (SNP) | VAF 19/470 reads (4%) | called by muse, mutect2
- DNAH5 | c.7431G>A p.Q2477= | Silent (SNP) | VAF 57/404 reads (14%) | catalogued as COSV54244786; called by muse, mutect2, varscan2
- FCRL4 | c.1203C>G p.L401= | Silent (SNP) | VAF 28/529 reads (5%) | called by muse, mutect2
- FMN2 | c.474G>T p.P158= | Silent (SNP) | VAF 50/305 reads (16%) | catalogued as rs1198977248, COSV60417397; called by muse, varscan2
- GPR107 | c.18C>T p.P6= | Silent (SNP) | VAF 88/208 reads (42%) | catalogued as rs760429542; called by muse, mutect2, varscan2
- IRX2 | c.1212C>A p.G404= | Silent (SNP) | VAF 36/842 reads (4%) | called by muse, mutect2
- KAT6B | c.5325C>T p.F1775= | Silent (SNP) | VAF 76/205 reads (37%) | catalogued as COSV104380587; called by muse, mutect2, varscan2
- KDELR1 | c.327C>G p.V109= | Silent (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- KIF21B | c.2436G>A p.L812= | Silent (SNP) | VAF 21/509 reads (4%) | catalogued as COSV100144495; called by muse, mutect2
- LGALS16 | c.315T>C p.N105= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- MAP11 | c.1335G>A p.R445= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV100385319; called by muse, mutect2, varscan2
- MAP6 | c.1473G>A p.G491= | Silent (SNP) | VAF 61/252 reads (24%) | called by muse, mutect2, varscan2
- NHLH2 | c.201G>A p.E67= | Silent (SNP) | VAF 102/315 reads (32%) | catalogued as rs1171289145; called by muse, mutect2, varscan2
- NKTR | c.2616C>G p.G872= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- NR5A2 | c.819C>T p.Y273= (on ENST00000367362 / NM_205860.3; = p.Y227= on NM_003822.5) | Silent (SNP) | VAF 20/368 reads (5%) | called by muse, mutect2
- OR10G4 | c.741C>A p.V247= | Silent (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- OR4K1 | c.615G>A p.L205= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV53459075; called by muse, mutect2, varscan2
- PCDH11X | c.2286C>T p.L762= | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.762T>C p.N254= | Silent (SNP) | VAF 47/204 reads (23%) | called by muse, mutect2, varscan2
- PML | c.2247C>A p.A749= | Silent (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- RHO | c.984G>C p.L328= | Silent (SNP) | VAF 44/254 reads (17%) | catalogued as rs1422707451, COSV56213728; called by mutect2, varscan2
- SCOC | c.81C>T p.F27= | Silent (SNP) | VAF 29/363 reads (8%) | called by muse, mutect2
- SHISA6 | c.1038C>A p.I346= (on ENST00000409168 / NM_001173461.1; = p.I397= on NM_207386.4) | Silent (SNP) | VAF 66/122 reads (54%) | catalogued as COSV101305754; called by muse, mutect2, varscan2
- SLC15A4 | c.1401T>C p.F467= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- SMC6 | c.1332A>G p.E444= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV61171767; called by muse, mutect2
- SPATA31D1 | c.468G>A p.V156= | Silent (SNP) | VAF 120/322 reads (37%) | catalogued as rs1281620925; called by muse, mutect2, varscan2
- SUGP1 | c.456G>A p.L152= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- TCF23 | c.258G>T p.R86= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV56079368; called by muse, varscan2
- TCF23 | c.339C>A p.S113= | Silent (SNP) | VAF 45/430 reads (10%) | called by muse, varscan2
- TENM1 | c.306G>A p.E102= | Silent (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- TMEM130 | c.786C>A p.T262= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs374694999; called by muse, mutect2, varscan2
- TMEM87A | c.1308G>A p.R436= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV67747291; called by muse, mutect2
- TNFRSF9 | c.534G>C p.A178= | Silent (SNP) | VAF 55/168 reads (33%) | catalogued as rs28360480, COSV66349966; called by muse, mutect2, varscan2
- TPGS1 | c.534G>C p.L178= | Silent (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- TSGA10IP | c.474T>C p.H158= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- TULP4 | c.81C>G p.P27= | Silent (SNP) | VAF 147/259 reads (57%) | catalogued as rs751287104; called by muse, mutect2, varscan2
- UNC5A | c.774C>T p.C258= | Silent (SNP) | VAF 84/299 reads (28%) | called by muse, mutect2, varscan2
- WDR11 | c.3372A>G p.K1124= | Silent (SNP) | VAF 42/451 reads (9%) | called by muse, mutect2
- ZNF394 | c.438C>T p.L146= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- AC048338.2 | c.*176C>G | 3'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- AC097518.1 | n.103G>T | RNA (SNP) | VAF 27/232 reads (12%) | called by muse, mutect2, varscan2
- AGPAT3 | c.*2743G>A | 3'UTR (SNP) | VAF 26/430 reads (6%) | catalogued as rs1011079452; called by muse, mutect2
- C4orf50 | c.-902G>T | 5'UTR (SNP) | VAF 71/240 reads (30%) | called by muse, mutect2, varscan2
- CD59 | c.*3C>G | 3'UTR (SNP) | VAF 32/467 reads (7%) | called by muse, mutect2
- CHRNA4 | c.*508C>G | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- COL21A1 | c.2408-55_2408-52del | Intron (DEL) | VAF 37/128 reads (29%) | called by mutect2, pindel, varscan2
- CTBP1 | c.*9G>A | 3'UTR (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- DOCK8 | c.3390+11A>T | Intron (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.-40C>A | 5'UTR (SNP) | VAF 20/211 reads (9%) | called by muse, mutect2
- GANC | c.201+2490T>C | Intron (SNP) | VAF 53/171 reads (31%) | called by muse, mutect2, varscan2
- GPC1 | c.167-5988C>T | Intron (SNP) | VAF 65/168 reads (39%) | catalogued as rs1370703850; called by muse, mutect2, varscan2
- GUSBP10 | n.140C>T | RNA (SNP) | VAF 87/249 reads (35%) | catalogued as rs567835031; called by muse, mutect2, varscan2
- LAMC3 | c.-9C>T | 5'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as rs1253412902; called by muse, mutect2, varscan2
- LETM2 | c.645+2844C>T | Intron (SNP) | VAF 62/182 reads (34%) | called by muse, mutect2, varscan2
- LETM2 | c.*4A>T | 3'UTR (SNP) | VAF 68/158 reads (43%) | called by mutect2, varscan2
- LINC02817 | n.223C>T | RNA (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2
- MED14 | c.-67del | 5'UTR (DEL) | VAF 60/100 reads (60%) | called by mutect2, pindel, varscan2
- MIR29A | n.53G>C | RNA (SNP) | VAF 4/48 reads (8%) | called by muse, varscan2
- MIR541 | n.35C>A | RNA (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- NEDD4L | c.2753-44C>G | Intron (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- OXT | c.*15G>A | 3'UTR (SNP) | VAF 71/190 reads (37%) | catalogued as rs17339677, COSV99459169; called by muse, mutect2, varscan2
- PHKB | c.2427+977C>G | Intron (SNP) | VAF 42/369 reads (11%) | called by muse, mutect2, varscan2
- PIP5K1C | c.-31C>T | 5'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159154 G>T | 5'Flank (SNP) | VAF 62/165 reads (38%) | called by muse, mutect2, varscan2
- SCMH1 | chr1:41161411 C>G | 5'Flank (SNP) | VAF 26/63 reads (41%) | called by muse, varscan2
- SH3YL1 | c.1+48G>C | Intron (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- SNX21 | c.*747C>G | 3'UTR (SNP) | VAF 25/274 reads (9%) | called by muse, mutect2
- SQLE | c.-897G>A | 5'UTR (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- STAG2 | c.-26G>C | 5'UTR (SNP) | VAF 20/26 reads (77%) | called by muse, mutect2, varscan2
- TBC1D31 | c.77+538G>A | Intron (SNP) | VAF 122/360 reads (34%) | called by muse, mutect2, varscan2
- TMEM92 | c.*37C>T | 3'UTR (SNP) | VAF 93/223 reads (42%) | called by muse, mutect2, varscan2
- TULP3 | c.*1113A>T | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- ZNF497 | c.-15+251C>T | Intron (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ZNRD2 | chr11:65572451 G>C | 3'Flank (SNP) | VAF 33/489 reads (7%) | called by muse, mutect2
